Surgical pathology report (de-identified scan), TCGA case TCGA-PK-A5H8, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University Health Network, specimen TCGA-PK-A5H8-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site [Ⓢ] Adrenal Gland, cortex
JND 1/8/13 C74.D

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	M	Reported:	
HCN:	[REDACTED]		
Ordering MD:			
Copy To:			

Specimen(s) Received

1. Adrenal: Right Adrenal Gland
2. superior medial margin of tumour

Diagnosis

1. Adrenocortical carcinoma with atrophy of normal adrenal cortex: Adrenal (right) adrenalectomy specimen
2. Cortical atrophy, negative for malignancy: Adrenal
No pathological diagnosis: Paraganglia and soft tissue
(superior medial margin) resection

Electronically verified by:

Clinical History

None given.

Gross Description

1. The specimen container labeled with the patient's name and as "adrenal right adrenal gland" contains an encapsulated mass that measures 19.5 x 13.5 x 6.5 cm and weighs 870 grams. The specimen has an intact capsule and has a red to gray colour. On section, the cut surface is solid, tan-brown and focally necrotic. Representative tumor tissue is stored frozen. Representative sections are submitted as follows:
1A-K representative sections
2. The specimen container labeled with the patient's name and as "superior medial margin of tumour" contains a single piece of unoriented brown soft tissue that measures 3.2 x 2.0 x 1.4 cm. The margins are painted with silver nitrate.
2A,B serially sectioned and submitted in toto.

Microscopic Description

1. Adrenal
DOMINANT LESION: Adrenocortical tumour
SIZE: 19.5 cm maximum dimension
WEIGHT: 870 grams
ARCHITECTURE: cellular lesion with predominantly solid nesting architecture

[page 2 of 2]
Surgical Pathology Consultation Report

CYTOLOGY: predominant compact cell morphology with focal clear cell change; nuclear atypia and pleomorphism with prominent nucleoli and frequent atypical mitotic figures

DEGENERATION: geographic and punctate necrosis

ENCAPSULATION: thick capsule

CAPSULAR INVASION: not identified

EXTRAADRENAL EXTENSION: not identified

RESECTION MARGINS: not involved

LYMPHOVASCULAR INVOLVEMENT: vascular invasion with thrombus identified in multiple areas

OTHER ADRENAL PATHOLOGY: atrophy of the normal cortex involving primarily the zona reticularis

LYMPH NODES: none identified

Source: NCI Genomic Data Commons file a81cc82a-8d87-4cdc-be8f-9b945399a7b8 (TCGA-PK-A5H8.706EC715-C6CD-49A9-8993-D6E5B20AED95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).